Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4923, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4923-01A (Primary Tumor).

Pathology Report

DIAGNOSIS

(A) LEFT KIDNEY AND ADRENAL:

RENAL CELL CARCINOMA (12.0 CM MAXIMUM DIMENSION), CONVENTIONAL TYPE
(70% CLEAR CELLS, 30%
EOSINOPHILIC CELLS), FUHRMAN NUCLEAR GRADE 4, INVASIVE INTO RENAL VEIN
AND RENAL
SINUS ADIPOSE TISSUE. (SEE COMMENT)

Margins of resection free of tumor.

Adrenal gland, no tumor present.

COMMENT

The renal cell carcinoma invades into the renal vein, but does not extend to the margin of resection. The tumor pushes into the perinephric adipose tissue, but there is no unequivocal invasion into the perinephric adipose tissue.

GROSS DESCRIPTION

(A) LEFT KIDNEY AND ADRENAL - A radical nephrectomy specimen (23.0 x 11.0 cm) including kidney and adrenal gland (6.7 x 4.0 x 1.0 cm).

Most of the kidney is replaced by a tumor (12.0 x 9.0 x 8.0 cm). The tumor has a variegated cut surface with areas ranging from soft light tan-brown to bright yellow and firm pink-white. Larger areas of the tumor are necrotic and cystic. The tumor invades into the renal vein, but does not extend to the renal vein margin of resection. Tumor pushes up against the perinephric adipose tissue. The renal sinus is completely obliterated by tumor.

The limited amount of renal parenchyma that is present is unremarkable. The adrenal gland is also unremarkable.

INK CODE: Black - Gerota's fascia.

SECTION CODE: A1, vascular margins; A2, tumor within renal vein; A3-A7, firm white areas of tumor (A5-A7, tumor with renal sinus); A8-A12, tan-yellow areas of tumor with renal sinus; A13-A15, tumor with perinephric adipose tissue and soft tissue margin; A16, non-neoplastic kidney; A17, normal adrenal gland. Tissue is also submitted for the renal vaccine protocol. [REDACTED]

CLINICAL HISTORY

Left renal mass.

[REDACTED]

Source: NCI Genomic Data Commons file 6b14f853-fbae-4d2c-ac13-4d2c37af251e (TCGA-CJ-4923.B51A1F35-2991-4277-9044-7761EBC5CADA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).